Gene-level copy-number profile of tumor specimen TCGA-77-8145-01A from TCGA case TCGA-77-8145, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.1 years (26,707 days).
Specimen TCGA-77-8145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1ec282cb-2155-4b6b-b7e8-bce31190f4ac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8145-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa703480-ec18-4f15-84f4-35ff64b2b3e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 12,178; copy number 2: 33,733; copy number 3: 9,838; copy number 4: 3,306; copy number 5: 87; copy number 6: 137; copy number 7: 379; copy number 8: 3; copy number 9: 23; copy number 10: 18; copy number 11: 72; copy number 31: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8145-01A-11D-2243-01): tumor purity 0.41, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:45,323,253–45,326,028, 1 gene: THAP12P9.
- chr9:90,020,654–90,433,566, 8 genes (within-gene range 0–2): MIR4290HG, MIR4290, IL6RP1, AL161629.2, AL353649.1, OR7E31P, OR7E116P, LINC01508.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 751 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,600,438–172,725,038, 135 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr3:172,771,277–172,771,405, 1 gene, copy number 6: SNORA72.
- chr3:172,889,357–173,336,965, 2 genes, copy number 8: SPATA16, AC068759.1.
- chr3:173,644,231–173,644,711, 1 gene, copy number 8: AC092967.1.
- chr3:176,415,439–176,867,838, 1 gene, copy number 7 (within-gene range 4–7): LINC01208.
- chr3:176,763,233–186,362,234, 201 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr3:191,641,135–192,767,764, 10 genes, copy number 7 (within-gene range 3–7): Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1.
- chr3:196,631,498–198,222,513, 54 genes, copy number 6: LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr9:88,324,454–89,606,555, 23 genes, copy number 5: RPSAP49, AL353748.3, SPIN1, AL353748.2, HNRNPA1P14, AL353748.1, NXNL2, LINC02843, AL390791.1, MIR4289, PCNPP2, AL772202.1, S1PR3, SHC3, AL353150.1, CKS2, MIR3153, SECISBP2, SEMA4D, PA2G4P6, AL590233.1, AL161910.1, GADD45G.
- chr9:131,370,933–132,890,201, 26 genes, copy number 5: AL354855.1, PRRC2B, SNORD62A, SNORD62B, AL358781.1, POMT1, AL358781.2, UCK1, PRRT1B, RAPGEF1, RN7SL328P, EIF4A1P3, AL160271.1, AL160271.2, MED27, NTNG2, SETX, TTF1, CFAP77, RNU5D-2P, BARHL1, DDX31, GTF3C4, AK8, AL445645.1, SPACA9.
- chr10:42,725,857–43,742,350, 36 genes, copy number 5: RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2, ZNF239, AL450326.3, CAP1P2, ZNF485, ZNF32-AS3, AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2, AL645634.1, SPRING1P1, UQCRHP3, ELOCP30.
- chr19:5,158,495–5,456,856, 5 genes, copy number 7 (within-gene range 2–7): PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4.
- chr20:87,250–11,621,477, 256 genes, copy number 7–31 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
